Gene-level copy-number profile of tumor specimen TCGA-HC-7080-01A from TCGA case TCGA-HC-7080, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.4 years (24,243 days).
Specimen TCGA-HC-7080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ef1a4c09-1c57-49c8-831e-5ef2281211bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-7080-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f8f502f-5885-4cb3-bcbf-23a097c3fb45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 235; copy number 1: 6,539; copy number 2: 52,495; copy number 3: 551.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-7080-01A-11D-1959-01): tumor purity 0.9, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 214 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,536,387–117,539,464, 1 gene: AC064856.1.
- chr2:136,199,114–139,825,877, 32 genes: HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1, THSD7B, RNA5SP105, Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1.
- chr2:140,216,997–142,131,016, 6 genes (within-gene range 0–1): MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157.
- chr2:140,992,543–145,931,146, 50 genes: Y_RNA, RNU6-904P, RPS16P3, AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1, Y_RNA, AC016910.1, GTDC1, ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412, TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5, AC092484.1, AC079163.2, AC079163.1, METAP2P1, AC079248.1, AC079248.2.
- chr2:185,950,469–188,839,445, 28 genes: AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1.
- chr4:128,292,751–129,377,504, 15 genes (within-gene range 0–1): LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2.
- chr5:86,746,818–86,749,777, 1 gene: LINC02059.
- chr5:87,863,703–88,904,257, 16 genes (within-gene range 0–1): AC114971.1, TMEM161B, TMEM161B-AS1, RNA5SP187, RPS3AP22, SNORA70, AC091826.1, LINC02060, AC091826.2, LINC00461, H3P23, MIR9-2, MEF2C-AS2, AC008525.1, AC008525.2, MEF2C.
- chr5:89,581,209–91,844,529, 29 genes: LINC02161, AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, AC093298.2, PCBP2P3, AC093298.1.
- chr5:98,768,650–100,153,779, 30 genes: RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P.
- chr5:100,535,374–100,903,282, 5 genes: FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P.
- chr10:52,389,112–52,389,488, 1 gene: RPL31P44.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
